Somatic mutation profile of cancer-model specimen HCM-BROD-0110-C25-85A (3D Organoid, passage 6; aliquot HCM-BROD-0110-C25-85A-01D-A786-36), derived from the primary tumor of HCMI case HCM-BROD-0110-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 64.1 years (23,410 days).
Specimen HCM-BROD-0110-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9d6133c-35d1-4c5d-853e-26881f327ea6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0110-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0110-C25-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70f60875-638c-4d6c-b423-ca14f465475e

The open-access MAF lists 84 somatic variants for this specimen: 64 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 17, Frame Shift Ins 4, Nonsense Mutation 3, 5'UTR 2, Splice Region 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 163/229 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.15536G>A p.R5179H | Missense Mutation (SNP) | VAF 132/251 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs267607237, CM105472, COSV56428259, COSV56447076, COSV56496109; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 136/313 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.594G>A p.P198= | Splice Region (SNP) | VAF 57/165 reads (35%) | catalogued as rs368308772; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 336/337 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 182/464 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV60916719; called by muse, mutect2, varscan2
- ACP6 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 90/155 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs146616655; called by muse, mutect2, varscan2
- ACVR2A | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1296122552, COSV54021353; called by muse, mutect2, varscan2
- CA5B | c.7G>A p.V3M | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.005); catalogued as rs150225380; called by muse, mutect2, varscan2
- CCDC171 | c.3577G>A p.G1193R | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.038); catalogued as rs372373322; called by muse, mutect2, varscan2
- CCDC178 | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 26/91 reads (29%) | catalogued as rs775027791, COSV55772123; called by muse, mutect2, varscan2
- CD69 | c.269T>G p.V90G | Missense Mutation (SNP) | VAF 26/432 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV57302683, COSV57303369; called by muse, mutect2
- CELSR2 | c.6562G>A p.E2188K | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.488); catalogued as rs139795794; called by muse, mutect2, varscan2
- CEP350 | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 121/315 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs549183005, COSV62606797; called by muse, mutect2, varscan2
- CFAP47 | c.9491G>A p.R3164H | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs1166928928, COSV66221408; called by muse, mutect2, varscan2
- CKAP5 | c.2030C>T p.T677M | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs768344282, COSV56364027; called by muse, mutect2
- CPLANE2 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs1045896146; called by muse, mutect2, varscan2
- CTNNB1 | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 198/432 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs1553630452, COSV62692500; ClinVar: other; called by muse, mutect2, varscan2
- DOCK2 | c.4381-6G>A | Splice Region (SNP) | VAF 162/333 reads (49%) | catalogued as rs944503145; called by muse, mutect2, varscan2
- FAT2 | c.12212G>A p.R4071H | Missense Mutation (SNP) | VAF 131/297 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1448093304, COSV55816556; called by muse, mutect2, varscan2
- FBXO38 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV57026947; called by muse, mutect2, varscan2
- GPR85 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 134/294 reads (46%) | SIFT tolerated (0.92); PolyPhen benign (0.028); catalogued as rs756442417, COSV51782887; called by muse, mutect2, varscan2
- IFT140 | c.2516C>T p.A839V | Missense Mutation (SNP) | VAF 174/340 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs145609033; called by muse, mutect2, varscan2
- IQCA1 | c.1921dup p.T641Nfs*14 | Frame Shift Ins (INS) | VAF 60/185 reads (32%) | catalogued as rs1559363996; called by mutect2, pindel, varscan2
- JAKMIP3 | c.2114T>C p.M705T | Missense Mutation (SNP) | VAF 178/392 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs757039698; called by muse, mutect2, varscan2
- MAP2K7 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 110/112 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185925179, COSV67607748, COSV67607971; called by muse, mutect2, varscan2
- MROH2B | c.3847G>A p.A1283T | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753717266, COSV68182483, COSV68182489; called by muse, mutect2
- NPAP1 | c.737C>A p.A246D | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61507801; called by muse, mutect2
- PLXNB2 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 188/241 reads (78%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as COSV63780090, COSV63780141; called by muse, mutect2, varscan2
- POM121L12 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 105/206 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs775755313, COSV68694032; called by muse, mutect2, varscan2
- PSD | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 142/313 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs766746185, COSV50065471; called by muse, mutect2, varscan2
- RP1 | c.5513G>A p.R1838H | Missense Mutation (SNP) | VAF 127/270 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs576959220; called by muse, mutect2, varscan2
- RPRD2 | c.3033T>A p.N1011K | Missense Mutation (SNP) | VAF 149/356 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs771368148; called by muse, mutect2, varscan2
- SCAF1 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 34/560 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs892425549, COSV62185030; called by muse, mutect2
- SCARA3 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs539385567; called by muse, mutect2, varscan2
- SH3BP4 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV60643280; called by muse, mutect2, varscan2
- SLITRK1 | c.709G>C p.G237R | Missense Mutation (SNP) | VAF 184/184 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100999721; called by muse, mutect2, varscan2
- SPTBN4 | c.5561G>A p.R1854Q | Missense Mutation (SNP) | VAF 101/150 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.134); catalogued as rs762520584; called by muse, mutect2, varscan2
- VWA2 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 30/339 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs775294430; called by muse, mutect2
- ZNF804B | c.2438A>G p.N813S | Missense Mutation (SNP) | VAF 76/140 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV60863770; called by muse, mutect2, varscan2
- BCOR | c.825_826insGGAT p.I276Gfs*26 | Frame Shift Ins (INS) | VAF 79/109 reads (72%) | called by mutect2, pindel, varscan2
- CD200R1 | c.923T>C p.V308A (on ENST00000471858 / NM_170780.3; = p.V331A on NM_138806.4) | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- COQ6 | c.45dup p.P16Sfs*22 | Frame Shift Ins (INS) | VAF 38/345 reads (11%) | called by mutect2, pindel, varscan2
- CWH43 | c.1330T>A p.W444R | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAJA2 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 104/215 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2317C>T p.Q773* | Nonsense Mutation (SNP) | VAF 35/208 reads (17%) | called by muse, mutect2, varscan2
- HAT1 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.088); called by muse, mutect2
- KCNH1 | c.2786T>C p.V929A (on ENST00000271751 / NM_172362.3; = p.V902A on NM_002238.4) | Missense Mutation (SNP) | VAF 181/447 reads (40%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAGED2 | c.967C>T p.R323* | Nonsense Mutation (SNP) | VAF 88/113 reads (78%) | called by muse, mutect2
- MEIS2 | c.1104C>A p.S368R (on ENST00000561208 / NM_170675.5; = p.S348R on NM_002399.3) | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- NAA25 | c.157A>C p.I53L | Missense Mutation (SNP) | VAF 103/207 reads (50%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NKPD1 | c.2344C>T p.R782W | Missense Mutation (SNP) | VAF 116/531 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- NPAS1 | c.617G>C p.G206A | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2
- OTUD7B | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 78/147 reads (53%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA6 | c.1369C>A p.Q457K | Missense Mutation (SNP) | VAF 208/833 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- PCDHGB3 | c.1843G>A p.G615R | Missense Mutation (SNP) | VAF 81/306 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RSPO4 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- SCMH1 | c.82T>A p.F28I | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SETD2 | c.4175dup p.N1392Kfs*6 | Frame Shift Ins (INS) | VAF 50/121 reads (41%) | called by mutect2, pindel, varscan2
- SLC35G4 | c.892T>G p.Y298D | Missense Mutation (SNP) | VAF 258/573 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, varscan2
- SMPD4 | c.175T>G p.S59A | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SOS2 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- STX18 | c.621T>G p.I207M | Missense Mutation (SNP) | VAF 66/97 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIO | c.6949G>A p.G2317S | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- BARX1 | c.561G>A p.K187= | Silent (SNP) | VAF 125/295 reads (42%) | called by muse, mutect2, varscan2
- CBLB | c.447C>A p.I149= | Silent (SNP) | VAF 127/264 reads (48%) | catalogued as COSV51427322; called by muse, mutect2, varscan2
- CRYBG2 | c.28C>A p.R10= | Silent (SNP) | VAF 30/64 reads (47%) | called by mutect2, varscan2
- CSDE1 | c.1995T>A p.T665= (on ENST00000358528 / NM_001007553.3; = p.T634= on NM_007158.6) | Silent (SNP) | VAF 76/189 reads (40%) | called by muse, mutect2, varscan2
- CSMD3 | c.3252G>A p.P1084= (on ENST00000297405 / NM_001363185.1; = p.P980= on NM_052900.3) | Silent (SNP) | VAF 146/329 reads (44%) | catalogued as rs762984316; called by muse, mutect2, varscan2
- DOP1A | c.2046A>G p.Q682= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as rs922471210; called by muse, mutect2, varscan2
- H2BU1 | c.297T>A p.V99= | Silent (SNP) | VAF 183/421 reads (43%) | called by muse, mutect2, varscan2
- MFSD2A | c.288C>T p.S96= (on ENST00000372809 / NM_001136493.3; = p.S83= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 108/243 reads (44%) | called by muse, mutect2, varscan2
- MMP17 | c.618C>T p.T206= | Silent (SNP) | VAF 136/269 reads (51%) | catalogued as rs747200830; called by muse, mutect2, varscan2
- PCDHA1 | c.1407G>A p.P469= | Silent (SNP) | VAF 389/874 reads (45%) | catalogued as COSV65374153; called by muse, mutect2, varscan2
- PCDHB12 | c.1683G>T p.V561= | Silent (SNP) | VAF 298/1022 reads (29%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.2085C>T p.I695= | Silent (SNP) | VAF 164/338 reads (49%) | called by muse, mutect2, varscan2
- TMTC1 | c.1083G>A p.A361= (on ENST00000539277 / NM_001193451.2; = p.A253= on NM_175861.3) | Silent (SNP) | VAF 67/140 reads (48%) | catalogued as rs751275421, COSV55482479; called by muse, mutect2, varscan2
- TRMT12 | c.738T>A p.G246= | Silent (SNP) | VAF 179/534 reads (34%) | called by muse, mutect2, varscan2
- ZFHX3 | c.3699C>T p.A1233= | Silent (SNP) | VAF 19/205 reads (9%) | catalogued as rs867245460; called by muse, mutect2
- ZNF536 | c.615C>T p.R205= | Silent (SNP) | VAF 252/368 reads (68%) | catalogued as rs745738230; called by muse, mutect2, varscan2
- ZNF597 | c.219C>T p.D73= | Silent (SNP) | VAF 72/142 reads (51%) | catalogued as rs569327096, COSV57083856; called by muse, mutect2, varscan2
- FLNB | c.-46C>T | 5'UTR (SNP) | VAF 166/394 reads (42%) | called by muse, mutect2, varscan2
- IMPACT | c.-76G>C | 5'UTR (SNP) | VAF 10/20 reads (50%) | called by muse, varscan2
- MIR655 | n.24G>C | RNA (SNP) | VAF 248/249 reads (100%) | called by muse, mutect2, varscan2
